TCGA case TCGA-CN-5363 — Head and Neck Squamous Cell Carcinoma (TCGA-HNSC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Larynx; Tissue source site: University of Pittsburgh. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/291b069c-9dde-4e1e-8430-85146bc94338

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 48 years; Vital status: Dead; Days to death: 253 days.

Diagnoses (2)
1. Squamous cell carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8070/3; ICD-10 code: C32.9; Tissue or organ of origin: Larynx, NOS; Site of resection or biopsy: Head, face or neck, NOS; Classification of tumor: primary; Age at diagnosis: 48.3 years (17,635 days); Year of diagnosis: 2007; AJCC staging edition: 6th; AJCC clinical T: T4a; AJCC clinical N: N3; AJCC clinical M: M0; AJCC clinical stage: Stage IVB; AJCC pathologic T: T4a; AJCC pathologic N: N3; AJCC pathologic M: M0; AJCC pathologic stage: Stage IVB; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Lymph node dissection method: Functional (Limited) Neck Dissection; Lymph node dissection site: Neck, Right.
   Pathology details: Lymph node dissection method: Modified Radical Neck Dissection; Lymph node dissection site: Neck, Left.
   Pathology details: Consistent pathology review: Yes; Extranodal extension: Microscopic Extension; Lymph nodes positive: 6; Lymph nodes tested: 28; Lymphatic invasion present: No; Margin status: Uninvolved; Perineural invasion present: No; Vascular invasion present: No.
2. Metastasis of diagnosis 1 (Squamous cell carcinoma, NOS), site: Bone, NOS. Age at diagnosis: 48.4 years (17,688 days); Days to diagnosis: 53 days; Prior treatment: Yes.
   Recorded as not given: Surgery, NOS to Distant Site, for progressive disease.

Follow-up (3 entries)
- Day 53 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Bone, NOS; Days to recurrence: 53 days.
- Day 53 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Bone, NOS; Days to progression: 53 days.
- Days to follow up: 253 days; Disease response: With Tumor.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker; Pack years smoked: 15; Tobacco smoking onset year: 1977.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-CN-5363-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 0.9; Intermediate dimension: 0.6; Shortest dimension: 0.6.
  Slide TCGA-CN-5363-01A-01-BS1: Section location: Bottom; Percent tumor cells: 90; Percent tumor nuclei: 70; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 10.
  Slide TCGA-CN-5363-01A-01-TS1: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 70; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 10.
- Sample TCGA-CN-5363-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-CN-5363-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Head and Neck; Histologic diagnosis: Head & Neck Squamous Cell Carcinoma; Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor; Lymph nodes examined: Yes; Lymph nodes examined IHC count: 0; Lymph node neck dissection indicator: Yes; Margin status: Negative; Lymphovascular invasion: No; Tobacco smoking history indicator: 2; Alcohol history documented: Yes.
- Follow-up form: New tumor event surgery: No; Tumor status: With tumor; New tumor event surgery met: No; New tumor event site: Distant Metastasis; New tumor event site other: Bone; Treatment outcome first course: Complete Remission/Response; Treatment outcome at TCGA followup: Persistent Disease.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 253 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 253 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 53 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-CN-5363-01A-01D-1432-01): tumor purity 0.51, ploidy 1.85, whole-genome doublings 0.
